Somatic mutation profile of tumor specimen TCGA-BP-5182-01A (aliquot TCGA-BP-5182-01A-01D-1429-08) from TCGA case TCGA-BP-5182, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 56.4 years (20,597 days).
Specimen TCGA-BP-5182-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cbd7c253-b38a-4280-b988-40b97846c0c8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-5182-11A (Solid Tissue Normal), aliquot TCGA-BP-5182-11A-01D-1429-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5a9580ba-1e80-4553-a3d4-641798d7d2e2

The open-access MAF lists 73 somatic variants for this specimen: 59 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 42, Silent 14, Nonsense Mutation 8, Frame Shift Del 5, Splice Site 1, Translation Start Site 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACSL3 | c.1657G>A p.D553N | Missense Mutation (SNP) | VAF 29/161 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV62484172; called by muse, mutect2, varscan2
- ADAMTS14 | c.1661G>C p.G554A | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.04); catalogued as COSV64605234; called by muse, mutect2, varscan2
- AOX1 | c.26T>G p.F9C | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768639507, COSV63416979; called by muse, mutect2
- APC2 | c.4581C>G p.H1527Q | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs566223544, COSV52021091; called by muse, mutect2, varscan2
- ARFGAP2 | c.854G>T p.R285L | Missense Mutation (SNP) | VAF 47/216 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV60301904; called by muse, mutect2, varscan2
- BAP1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.255); catalogued as COSV56232191, COSV56233932; called by muse, mutect2, varscan2
- BBS1 | c.22G>A p.D8N | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as COSV59151022; called by muse, mutect2, varscan2
- CARS1 | c.1234A>C p.K412Q | Missense Mutation (SNP) | VAF 45/224 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53458640; called by muse, mutect2, varscan2
- CLTCL1 | c.3942G>T p.M1314I | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV54236866; called by muse, mutect2, varscan2
- CPS1 | c.254C>G p.T85S | Missense Mutation (SNP) | VAF 75/337 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV51820380; called by muse, mutect2, varscan2
- DCDC2B | c.578C>G p.T193S | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52210641; called by muse, mutect2, varscan2
- DDX46 | c.2749G>T p.E917* | Nonsense Mutation (SNP) | VAF 31/104 reads (30%) | catalogued as COSV62799656; called by muse, mutect2, varscan2
- DNAJB1 | c.348dup p.G117Wfs*12 | Frame Shift Ins (INS) | VAF 28/170 reads (16%) | catalogued as rs1239666815; called by mutect2, pindel, varscan2
- DST | c.6919C>A p.Q2307K | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.172); catalogued as rs747767227, COSV55033093, COSV99757322; called by muse, mutect2, varscan2
- EFCC1 | c.1314G>T p.M438I | Missense Mutation (SNP) | VAF 30/180 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs1231070121, COSV71402099; called by muse, mutect2, varscan2
- EIF1 | c.144A>T p.Q48H | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.518); catalogued as COSV60422299, COSV60422902; called by muse, mutect2, varscan2
- ETNPPL | c.83C>A p.S28* | Nonsense Mutation (SNP) | VAF 40/219 reads (18%) | catalogued as rs776914976, COSV56597022, COSV56597727, COSV56598085; called by muse, mutect2, varscan2
- EXPH5 | c.2718C>A p.F906L | Missense Mutation (SNP) | VAF 61/331 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.22); catalogued as COSV56206718; called by muse, mutect2, varscan2
- FEZ1 | c.965A>C p.N322T | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.062); catalogued as COSV54030896; called by muse, mutect2, varscan2
- FNTB | c.327C>G p.H109Q | Missense Mutation (SNP) | VAF 37/245 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.303); catalogued as COSV55763414; called by muse, mutect2, varscan2
- G2E3 | c.977A>T p.Q326L | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as COSV52842225; called by muse, mutect2
- JAK3 | c.2240C>A p.P747H | Missense Mutation (SNP) | VAF 21/182 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV71687068; called by muse, mutect2, varscan2
- KIF14 | c.2596G>A p.E866K | Missense Mutation (SNP) | VAF 57/300 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as COSV66263355; called by muse, mutect2, varscan2
- KIF21B | c.3031-1G>A p.X1011_splice | Splice Site (SNP) | VAF 20/90 reads (22%) | catalogued as COSV59763675; called by muse, mutect2, varscan2
- KLHDC8B | c.661G>A p.E221K | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.524); catalogued as COSV60412404; called by muse, mutect2, varscan2
- KMT2A | c.8662G>T p.E2888* | Nonsense Mutation (SNP) | VAF 88/427 reads (21%) | catalogued as COSV63290624; called by muse, mutect2, varscan2
- KRTAP12-1 | c.172G>A p.V58M | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.889); catalogued as rs539596533, COSV59974190; called by muse, mutect2
- MYO5A | c.707G>C p.G236A | Missense Mutation (SNP) | VAF 22/332 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV62563314; called by muse, mutect2
- MZB1 | c.183G>A p.W61* | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | catalogued as COSV56172885; called by muse, mutect2
- NAF1 | c.25G>T p.A9S | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.982); catalogued as COSV56805553; called by muse, mutect2
- NEB | c.1754C>A p.A585D | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV51446246; called by muse, mutect2, varscan2
- NUP88 | c.222A>T p.E74D | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV56707387; called by muse, mutect2, varscan2
- OR7A10 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.556); catalogued as COSV50166352, COSV50166669; called by muse, mutect2, varscan2
- PCDHA1 | c.463G>T p.E155* | Nonsense Mutation (SNP) | VAF 14/262 reads (5%) | catalogued as COSV65376247; called by muse, mutect2
- PRIM1 | c.504G>A p.W168* | Nonsense Mutation (SNP) | VAF 18/121 reads (15%) | catalogued as COSV57717951; called by muse, mutect2, varscan2
- PYDC1 | c.8C>G p.T3R | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs546281460, COSV100265352, COSV57251976; called by muse, mutect2, varscan2
- SEC31B | c.3086A>T p.E1029V | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.611); catalogued as COSV64845376; called by muse, mutect2, varscan2
- SPEN | c.373C>T p.R125* | Nonsense Mutation (SNP) | VAF 19/127 reads (15%) | catalogued as COSV65366181; called by muse, mutect2, varscan2
- SPSB1 | c.197T>C p.F66S | Missense Mutation (SNP) | VAF 47/259 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.841); catalogued as COSV60164239; called by muse, mutect2, varscan2
- SRCAP | c.5075G>C p.G1692A | Missense Mutation (SNP) | VAF 70/319 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); catalogued as COSV52678580; called by muse, mutect2, varscan2
- SULT1A1 | c.851T>A p.M284K | Missense Mutation (SNP) | VAF 9/154 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100131778; called by muse, mutect2
- TAF5 | c.718T>G p.F240V | Missense Mutation (SNP) | VAF 57/250 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.606); catalogued as COSV60857720; called by muse, mutect2, varscan2
- TLR1 | c.588C>A p.F196L | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as COSV58305239; called by muse, mutect2, varscan2
- TRANK1 | c.8203G>T p.G2735C | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as COSV57143035, COSV57160597; called by muse, mutect2, varscan2
- UBE4B | c.1112G>A p.R371K | Missense Mutation (SNP) | VAF 49/182 reads (27%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.011); catalogued as rs375249164; called by muse, mutect2, varscan2
- USP48 | c.2318C>T p.A773V | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.8); PolyPhen benign (0.023); catalogued as COSV57613239; called by muse, mutect2, varscan2
- VHL | c.383T>A p.L128H | Missense Mutation (SNP) | VAF 70/272 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM040270, CM093522, COSV56544329, COSV56550485, COSV56556920; called by muse, varscan2
- ZBTB20 | c.1997T>C p.I666T (on ENST00000474710 / NM_001164342.2; = p.I593T on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 68/314 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.538); catalogued as COSV61862909; called by muse, mutect2, varscan2
- ZMYND11 | c.1736C>A p.S579Y | Missense Mutation (SNP) | VAF 61/288 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59080921; called by muse, mutect2, varscan2
- ARHGAP25 | c.1016del p.I339Tfs*4 (on ENST00000409202 / NM_001007231.3; = p.I331Tfs*4 on NM_014882.3) | Frame Shift Del (DEL) | VAF 102/577 reads (18%) | called by mutect2, pindel, varscan2
- DHX33 | c.2093_2094del p.F698* | Frame Shift Del (DEL) | VAF 9/75 reads (12%) | called by mutect2, pindel, varscan2
- FLNC | c.2550+1del | Frame Shift Del (DEL) | VAF 14/63 reads (22%) | called by mutect2, pindel, varscan2
- GPR179 | c.3058C>A p.H1020N (on ENST00000621958; = p.H1019N on NM_001004334.4) | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT tolerated (0.81); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IGHV3-20 | c.14T>A p.L5Q | Missense Mutation (SNP) | VAF 62/321 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- KLHL36 | c.1024del p.V342Cfs*42 | Frame Shift Del (DEL) | VAF 10/38 reads (26%) | called by mutect2, pindel, varscan2
- PRAMEF10 | c.1033G>T p.E345* | Nonsense Mutation (SNP) | VAF 59/698 reads (8%) | called by muse, mutect2
- PTPRB | c.2092del p.S698Pfs*13 | Frame Shift Del (DEL) | VAF 6/14 reads (43%) | called by mutect2, varscan2
- PTPRB | c.2091T>G p.C697W | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- TRPM4 | c.673_684del p.L225_N228del | In Frame Del (DEL) | VAF 12/89 reads (13%) | called by mutect2, pindel, varscan2
- ARHGAP25 | c.963C>A p.L321= (on ENST00000409202 / NM_001007231.3; = p.L313= on NM_014882.3) | Silent (SNP) | VAF 13/97 reads (13%) | catalogued as COSV54906485; called by muse, mutect2, varscan2
- CCDC78 | c.288G>A p.R96= | Silent (SNP) | VAF 17/84 reads (20%) | catalogued as rs532009000, COSV52403836; called by muse, mutect2, varscan2
- DENND2D | c.807G>A p.Q269= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as rs763768849, COSV62959794; called by muse, mutect2, varscan2
- H1-0 | c.96C>T p.I32= | Silent (SNP) | VAF 23/122 reads (19%) | catalogued as rs151035348; called by muse, mutect2, varscan2
- HAS3 | c.1642T>C p.L548= | Silent (SNP) | VAF 21/140 reads (15%) | catalogued as rs375357316; called by muse, mutect2, varscan2
- IGHG3 | c.486T>A p.P162= | Silent (SNP) | VAF 16/88 reads (18%) | called by muse, mutect2, varscan2
- LIMK2 | c.1800C>A p.S600= | Silent (SNP) | VAF 114/599 reads (19%) | catalogued as COSV53224293; called by muse, mutect2, varscan2
- LRRC4 | c.213G>A p.Q71= | Silent (SNP) | VAF 28/165 reads (17%) | catalogued as COSV50816947; called by muse, mutect2, varscan2
- POLR1A | c.379C>T p.L127= | Silent (SNP) | VAF 72/352 reads (20%) | catalogued as COSV55697624; called by muse, mutect2, varscan2
- SKIV2L | c.1254G>A p.E418= | Silent (SNP) | VAF 30/149 reads (20%) | catalogued as COSV64813558; called by muse, mutect2, varscan2
- SNRK | c.1947C>T p.L649= | Silent (SNP) | VAF 22/74 reads (30%) | catalogued as COSV56070084; called by muse, varscan2
- TLL2 | c.792C>A p.T264= | Silent (SNP) | VAF 29/96 reads (30%) | catalogued as COSV63574853; called by muse, mutect2, varscan2
- TMEM87A | c.1419A>T p.P473= | Silent (SNP) | VAF 45/298 reads (15%) | catalogued as COSV67747787; called by muse, mutect2, varscan2
- TRAF5 | c.1479G>A p.K493= | Silent (SNP) | VAF 21/116 reads (18%) | catalogued as COSV54824119; called by muse, mutect2, varscan2
